Somatic mutation profile of tumor specimen TCGA-AB-2817-03B (aliquot TCGA-AB-2817-03B-01W-0728-08) from TCGA case TCGA-AB-2817, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.0 years (23,376 days).
Specimen TCGA-AB-2817-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fff882cb-4223-4472-a28a-3fc75f1d9b49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2817-11B (Solid Tissue Normal), aliquot TCGA-AB-2817-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2c84dd1-1c0e-4a26-ae95-cb5e9ba1b3c3

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3S2 | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs753501097, COSV60519842; called by muse, mutect2, varscan2
- BRINP3 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66522433; called by muse, mutect2, varscan2
- CYC1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV100010514; called by muse, mutect2
- CYP26A1 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs752745616, COSV56419827; called by muse, mutect2, varscan2
- GPR6 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.895); catalogued as COSV51573517; called by muse, mutect2, varscan2
- SSTR4 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs752836318, COSV54797852, COSV99658387; called by muse, mutect2, varscan2
- TCAF1 | c.578T>C p.F193S | Missense Mutation (SNP) | VAF 72/85 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV63518771; called by muse, mutect2, varscan2
- TRNT1 | c.1246A>G p.K416E | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs199931785, CM1411168, COSV51642664; called by muse, mutect2, varscan2
